CPTAC case C3N-01846 — Bronchus and lung — Squamous Cell Neoplasms (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Squamous Cell Neoplasms; Primary site: Bronchus and lung. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/8d1b6812-9c39-4e83-b6d4-8091f9ff6018

Demographics
Sex at birth: male; Race: white; Year of birth: 1947; Vital status: Dead; Days to death: 533 days (1.5 years); Year of death: 2018; Cause of death: Cancer Related; Country of birth: Ukraine.

Diagnoses (1)
1. Squamous cell carcinoma, NOS: ICD-O-3 morphology code: 8070/3; Tissue or organ of origin: Lung, NOS; Site of resection or biopsy: Middle lobe, lung; Age at diagnosis: 69.9 years (25,518 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: M0; AJCC pathologic T: T2a; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage IB; Tumor grade: G2; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 533 days (1.5 years); Progression or recurrence: yes; Days to last follow up: 533 days (1.5 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved.

Follow-up (2 entries)
- Days to follow up: 269 days; Disease response: With Tumor.
- Days to follow up: 533 days (1.5 years); Disease response: With Tumor; Progression or recurrence: Yes; Days to recurrence: 415 days (1.1 years).

Other clinical attributes
- Weight: 72 kg; Height: 168 cm; BMI: 25.51.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (12 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01846-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 61 days; Initial weight: 400 mg; Time between clamping and freezing: 25 minutes; Time between excision and freezing: 10 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01846-21: Section location: Right Middle Lobe; Percent tumor nuclei: 70; Percent necrosis: 10.
- Sample C3N-01846-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 410 mg.
- Sample C3N-01846-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 420 mg.
- Sample C3N-01846-06: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Biospecimen laterality: Right; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 61 days; Initial weight: 180 mg; Time between clamping and freezing: 27 minutes; Time between excision and freezing: 12 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3N-01846-31, C3N-01846-32, C3N-01846-72, C3N-01846-73, C3N-01846-74, C3N-01846-75, C3N-01846-76 (7 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
- Sample C3N-01846-71: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 61 days; Method of sample procurement: Blood Draw.
